Gene-level copy-number profile of tumor specimen TCGA-29-1707-02A from TCGA case TCGA-29-1707, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 41.1 years (15,017 days).
Specimen TCGA-29-1707-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f71f4047-5a0f-45d3-ac81-d0610a19c3b9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1707-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate.
https://portal.gdc.cancer.gov/files/c6adc92b-cbf3-4aa9-8be8-03b6127b96df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 686; copy number 1: 15,584; copy number 2: 37,535; copy number 3: 3,917; copy number 4: 2,427; copy number 5: 108; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 166 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,585,444–185,956,652, 6 genes: SORBS2, AC093797.1, AC108472.1, Y_RNA, AC104805.1, AC096659.1.
- chr8:18,391,282–18,401,218, 1 gene: NAT2.
- chr17:11,598,470–12,642,854, 13 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1.
- chr17:12,671,862–12,706,135, 1 gene (within-gene range 0–1): MYOCD-AS1.
- chr17:19,579,943–19,596,058, 1 gene (within-gene range 0–1): SLC47A1P1.
- chr17:19,600,860–22,706,703, 143 genes (broad region; genes not listed).
- chr17:40,977,716–40,987,135, 1 gene (within-gene range 0–1): KRT40.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 120 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:80,972,516–81,199,115, 3 genes, copy number 5: AC004972.1, AC005008.2, AC005008.1.
- chr7:107,044,705–108,721,601, 32 genes, copy number 5–6: PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1.
- chr15:99,098,217–101,933,350, 85 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
